Gene-level copy-number profile of tumor specimen C3N-03449-01 from CPTAC case C3N-03449, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.6 years (21,763 days).
Specimen C3N-03449-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9612c2c4-e09c-4a28-bf29-b2c32c1eea54.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03449-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/1717f174-8c5b-4028-9a72-0c29ef918c1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 5,708; copy number 2: 43,238; copy number 3: 9,895; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,113,549–5,114,804, 1 gene (within-gene range 0–2): IGHEP2.
- chr9:10,532,145–10,532,411, 1 gene (within-gene range 0–2): AL135790.2.
- chr9:14,850,429–14,850,535, 1 gene (within-gene range 0–2): RNU6-1260P.
- chr9:21,165,637–22,455,740, 49 genes: IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:39,816,542–40,106,661, 1 gene (within-gene range 0–2): FGF7P3.
- chr9:39,886,861–40,122,540, 7 genes: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14.
- chr9:40,131,747–40,132,218, 1 gene (within-gene range 0–1): AL773545.2.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,014,285–57,020,273, 1 gene, copy number 8: SLC29A4P1.

Autosomal genes at a single copy (total copy number 1): 2,854. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
